CCDI case PBBRKP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2bf253c3-1373-4c05-ba92-5e4b073cbca3

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.8 years (1,770 days).

Biospecimens (4 samples)
- Sample 0DEV2G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DEV3S, 0DEYGK (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF0DO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
